Surgical pathology report (de-identified scan), TCGA case TCGA-06-0132, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0132-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED] 09-0132 [REDACTED]

[REDACTED]

CLINICAL HISTORY

[REDACTED] has history of confusion and memory problem for a couple of weeks, and an irregularly enhancing mass with necrotic center and marked edema and mass effect in the right parietal temporal lobes.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain tumor, biopsy
B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, parietal lobe, excision: Glioblastoma.
See Comment.

COMMENT

In parts A and B there is an astrocytic neoplastic proliferation with nuclear anaplasia, mitotic figures, microvascular proliferation with vascular necrosis and thrombosis, and areas of necrosis. A large proportion of part B is necrotic tumor.

Special stains to better characterize the tumor have been requested, and will be reported as an addendum.

[REDACTED]

Interpretation

NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Received were paraffin curls labeled [REDACTED] [REDACTED]

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

[REDACTED]

[page 2 of 3]
[REDACTED]

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

Interpretation

MIB-1 proliferation index: 7%.
See Results and Comment (below).

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates prominent glial fibrillogenesis by the neoplastic cells. With the MIB-1 there is a proliferation index of about 7% in the more active areas.

Comment: The immuno results are consistent with a high histological grade astrocytic neoplasm.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain tumor, biopsy, touch preps and smears: Glioma, high histological grade (C/W glioblastoma). [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.
Received fresh, three fragments, 1.0-cm. in aggregate. Semi firm, creamy-white, glistening. In total, A1.

B.
SPECIMEN: Brain tumor.
FIXATIVE: Formalin.
GENERAL: A 3.0 x 2.5 x 1.4 cm., 1.75 gm. aggregate of several red to gray-tan tissue fragments, Some of the larger fragments are sectioned.
SECTIONS: B1-B3 all submitted.

[REDACTED]

[REDACTED]

[page 3 of 3]
Histo Data

Part A: Brain tumor, biopsy

Stain/cnt	Block	Ordered	Comment
H/E x 1	1		

Part B: Brain, excision biopsy

Stain/cnt	Block	Ordered	Comment
mGFAP-DA x 1	1		
H/E x 1	1		
MGMT x 1	1		
MIB1-DA x 1	1		
H/E x 1	2		
H/E x 1	3		

*** End of Report ***

Source: NCI Genomic Data Commons file 2015045a-8693-4e89-a413-46abe8afa4ef (TCGA-06-0132.B572CEE6-5C7E-402B-A25D-CD380594C7DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).